Somatic mutation profile of tumor specimen 0DCX9W from CCDI case PBBMIZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 8.0 years (2,939 days).
Specimen 0DCX9W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2093a1d4-ad86-4057-8e78-d3c6f63e89fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCX8Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d84d93e2-22d8-49fb-a8bc-f5e78aac5198

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2C | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs762842488; called by muse, varscan2
- ITGAL | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 128/332 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs771815313; called by muse, varscan2
- PCED1B | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71395199; called by muse, varscan2
- RABL6 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); catalogued as rs372444796; called by muse, varscan2
- TKTL2 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 214/630 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs779776530; called by muse, varscan2
- TRIP10 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 158/472 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1287022392; called by muse, varscan2
- ALPK2 | c.2030C>A p.A677D | Missense Mutation (SNP) | VAF 114/590 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, varscan2
- APPBP2 | c.473A>C p.H158P | Missense Mutation (SNP) | VAF 484/1167 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, varscan2
- DST | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 374/999 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- ABCG5 | c.93C>T p.T31= | Silent (SNP) | VAF 94/226 reads (42%) | catalogued as rs368621082; called by muse, varscan2
- ACOT2 | c.697C>T p.L233= | Silent (SNP) | VAF 256/640 reads (40%) | called by muse, varscan2
- PLK1 | c.1143G>T p.L381= | Silent (SNP) | VAF 42/374 reads (11%) | called by muse, varscan2
- RHOXF2B | c.309C>T p.N103= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as COSV65054910; called by muse, varscan2
